Somatic mutation profile of tumor specimen MP2PRT-PATAVL-TMP1-A (aliquot MP2PRT-PATAVL-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PATAVL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.9 years (2,532 days).
Specimen MP2PRT-PATAVL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c2147c1-6557-4f30-ad3b-bc98d0902adb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATAVL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATAVL-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0514ab62-80c1-45ad-b2d8-1b1f05df6978

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 9, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.7933C>T p.R2645* | Nonsense Mutation (SNP) | VAF 17/542 reads (3%) | catalogued as rs1555191740, CM111915, COSV56409935; ClinVar: pathogenic; called by muse, mutect2
- ADCY4 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 72/193 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147496401; called by muse, mutect2, varscan2
- ANO3 | c.1912G>A p.A638T | Missense Mutation (SNP) | VAF 96/260 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.136); catalogued as rs139205902; called by muse, mutect2, varscan2
- DCT | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 95/256 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs151208955, COSV65470015; called by muse, mutect2, varscan2
- PAX5 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 189/485 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63908111; called by muse, mutect2, varscan2
- PCDH11X | c.2971G>A p.V991I | Missense Mutation (SNP) | VAF 223/613 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.044); catalogued as rs373159801; called by muse, varscan2
- TRPV3 | c.1196C>T p.T399M | Missense Mutation (SNP) | VAF 145/383 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.197); catalogued as rs367883200, COSV56796486; called by muse, mutect2, varscan2
- ZEB2 | c.3113A>G p.H1038R | Missense Mutation (SNP) | VAF 35/517 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57953045; called by muse, mutect2
- DLGAP5 | c.304C>A p.Q102K | Missense Mutation (SNP) | VAF 70/224 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.011); called by muse, varscan2
- INSRR | c.2192C>T p.T731M | Missense Mutation (SNP) | VAF 325/623 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR4S1 | c.603C>T p.S201= | Silent (SNP) | VAF 147/392 reads (38%) | catalogued as rs775526379, COSV60678945; called by muse, mutect2, varscan2
- PDZD8 | c.2082A>G p.T694= | Silent (SNP) | VAF 22/424 reads (5%) | called by muse, mutect2
- SAV1 | c.354G>T p.T118= | Silent (SNP) | VAF 69/221 reads (31%) | catalogued as COSV61205767; called by muse, mutect2, varscan2
